Somatic mutation profile of tumor specimen 0DN51P from CCDI case PBCBHK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.3 years (2,313 days).
Specimen 0DN51P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe1c807f-eb53-4b55-b709-4fbbde74e9c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN51J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55965600-72a4-4e64-ab3c-7ec918a065ee

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCH2 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 285/559 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1231393639; called by muse, mutect2, varscan2
- SLITRK3 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 152/780 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs375753103; called by muse, mutect2, varscan2
- PRPF8 | c.5527G>A p.E1843K | Missense Mutation (SNP) | VAF 56/626 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLRF2 | c.501T>G p.T167= | Silent (SNP) | VAF 34/802 reads (4%) | called by muse, mutect2
- SNORD3B-2 | n.280G>C | RNA (SNP) | VAF 53/1688 reads (3%) | catalogued as rs1213021267; called by muse, mutect2
